Surgical pathology report (de-identified scan), TCGA case TCGA-43-A56U, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-A56U-01A (Primary Tumor).

[page 1 of 2]
UUID:51B3CSAA-AF5B-4976-AFE0-0E6BEAA3D6B6

Final Surgical Pathology Report

Procedure:

Diagnosis

A,B,C. Lymph nodes, L10, level 11, and level 5, excisions -
Negative for malignancy.

D. Lung, left upper lobe, excision -

Poorly differentiated squamous cell carcinoma (see microscopic
description).

Margins negative for malignancy.

Two hilar lymph nodes negative for malignancy

Microscopic Description:

Histologic type: Squamous cell carcinoma comprising the mass lesion in
the left upper lobe, part D

Histologic grade: Poorly differentiated

Primary tumor (pT): The tumor is 2.1 cm in greatest dimension, without
pleural invasion present (pT1b)

Margins of resection: The bronchial and vascular resection margins are
negative for tumor

Direct extension of tumor: Not identified

Vascular invasion: Not identified

Regional lymph nodes (pN): pN0. The separately submitted lymph nodes
in parts A, B, and C, as well as two hilar lymph nodes that are
identified in part D, are negative for tumor

Distant metastasis (pM): Not applicable

Comment: has reviewed this case and concurs with the
interpretation

Specimen

- A. L10 lymph node
- B. Level 11
- C. Level 5
- D. Left upper lobe

Clinical Information

PRE-OP DIAGNOSIS: Lung cancer

Gross Description

A. Received fresh in a container labeled "L10 lymph node" are multiple
irregular soft pink-black tissue fragments, in aggregate 1 x 1 x 0.3
cm. Due to fragmentation, it is not possible to enumerate lymph nodes.
AS-1, following fixation.

B. Received fresh in a container labeled "level 11" is a 0.8 x 0.5 x
0.3 cm soft pink-red irregular tissue fragment. AS-1, following
fixation.

C. Received fresh in a container labeled "level 5" is a 1 x 1 x 0.5 cm
soft black-pink irregular tissue fragment. It is sectioned. AS-1,
following fixation.

D. Received fresh in a container labeled "left upper lobe" is a 25 x 8
x 4 cm lobe of lung compatible with left upper lobe. The pleural
surface is pink-tan, smooth, and glistening, with diffuse black
stippling present. The pleural surface is inked blue. Sectioning

ICD-O-3

Carcinoma, squamous cell, NOS

8670/3

Site:

② Lung, upper lobe

C34.1

4/29/12

[page 2 of 2]
BLOCK SUMMARY: D1 - hilar lymph nodes; D2 - bronchial & vascular margin; D3-D6 - entire lesion; D7 - lung away from lesion.

	Yes	No
Life in		
Continuous Discrepancy		
Primary/Target Site Discrepancy		
Local Discrepancy		
Other Discrepancy History		
Major/Continuous/Target Site		
Site is correct		
Signature Initials		
Date Interviewed		

Source: NCI Genomic Data Commons file b6e470c3-1fd8-42e2-8ce5-52453d88ebac (TCGA-43-A56U.51B3C5AA-AF58-4976-AFE0-0E6BEAA3D6B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).